Somatic mutation profile of tumor specimen TCGA-DU-7309-01A (aliquot TCGA-DU-7309-01A-11D-2086-08) from TCGA case TCGA-DU-7309, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, anaplastic; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 41.6 years (15,197 days).
Specimen TCGA-DU-7309-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f46efb0f-136f-47b9-97ff-c9cd6fad9c31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DU-7309-10A (Blood Derived Normal), aliquot TCGA-DU-7309-10A-01D-2086-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f639905-fe01-46ff-9335-af3a0369fa09

The open-access MAF lists 39 somatic variants for this specimen: 32 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 28, Silent 7, Nonsense Mutation 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH2 | c.516G>T p.R172S | Missense Mutation (SNP) | VAF 27/75 reads (36%) | hotspot (GDC flag); SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57468772, COSV57468910, COSV57481094; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 76/116 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABHD16A | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.272); catalogued as COSV65452593; called by muse, mutect2, varscan2
- ACSM1 | c.1199T>C p.V400A | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV54633564; called by muse, mutect2, varscan2
- ATRX | c.6607G>T p.E2203* | Nonsense Mutation (SNP) | VAF 51/116 reads (44%) | catalogued as COSV64874625, COSV64883178; called by muse, mutect2, varscan2
- BNIP2 | c.859A>G p.M287V | Missense Mutation (SNP) | VAF 35/93 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.349); catalogued as rs201360063; called by muse, mutect2, varscan2
- CEP68 | c.241C>G p.P81A | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV53127510; called by muse, varscan2
- CXCR2 | c.109G>A p.A37T | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs75759064; called by muse, mutect2, varscan2
- DNAJC11 | c.1390A>G p.I464V | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as rs1372285197, COSV50011760; called by muse, mutect2
- EPB41L3 | c.2725G>C p.V909L | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.044); catalogued as COSV59467551; called by muse, mutect2
- ERC1 | c.1252G>A p.E418K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.377); catalogued as COSV61699473; called by muse, mutect2, varscan2
- GABRA6 | c.1181C>T p.A394V | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs761702862, COSV50883828, COSV99194556; called by muse, mutect2, varscan2
- GNAO1 | c.84C>G p.I28M | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV52620447; called by muse, mutect2, varscan2
- KRT6C | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs140943956; called by muse, mutect2, varscan2
- LACTB2 | c.4G>C p.A2P | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.143); catalogued as COSV52569579; called by muse, mutect2
- MBNL3 | c.744G>C p.Q248H | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as COSV63731630; called by muse, mutect2
- MTTP | c.1928T>C p.L643P | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV55509774; called by muse, mutect2
- NOA1 | c.1580G>C p.R527T | Missense Mutation (SNP) | VAF 4/87 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51738725, COSV99950729; called by muse, mutect2
- OVGP1 | c.438A>T p.R146S | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV63860078; called by muse, mutect2, varscan2
- PCMT1 | c.415A>G p.K139E | Missense Mutation (SNP) | VAF 55/148 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs767103869, COSV66304138; called by muse, mutect2, varscan2
- PGLYRP4 | c.471A>G p.K157= | Splice Region (SNP) | VAF 22/50 reads (44%) | catalogued as COSV62836363; called by muse, mutect2, varscan2
- PLCZ1 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs200642156; called by muse, mutect2
- PPP1CB | c.808A>T p.N270Y | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.744); catalogued as COSV56091963; called by muse, mutect2, varscan2
- PYGB | c.1247C>G p.A416G | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV53822765; called by muse, mutect2, varscan2
- SEMA6A | c.1760C>G p.T587S | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.043); catalogued as rs769403156, COSV56714910; called by muse, mutect2, varscan2
- SLC39A13 | c.559G>A p.A187T | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.258); catalogued as COSV61522744; called by muse, mutect2, varscan2
- SUGCT | c.1213G>A p.G405R (on ENST00000335693 / NM_001193313.2; = p.G431R on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/206 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs778799455, COSV59353134; called by muse, mutect2, varscan2
- TEX11 | c.391G>T p.E131* (on ENST00000344304; = p.E116* on NM_031276.3) | Nonsense Mutation (SNP) | VAF 17/60 reads (28%) | catalogued as COSV60239034, COSV60239997; called by muse, mutect2, varscan2
- TLCD3B | c.383A>G p.K128R | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.6); PolyPhen benign (0.223); catalogued as COSV54228173; called by muse, mutect2, varscan2
- VAV1 | c.1040C>T p.T347M | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58391355; called by muse, mutect2
- ZNF318 | c.3100C>T p.R1034C | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs147313268; called by muse, mutect2, varscan2
- ZACN | c.533_534del p.L178Qfs*28 | Frame Shift Del (DEL) | VAF 42/141 reads (30%) | called by pindel, varscan2
- CEP68 | c.243A>G p.P81= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV53127518; called by muse, mutect2, varscan2
- MUC17 | c.13260G>C p.V4420= | Silent (SNP) | VAF 9/39 reads (23%) | catalogued as COSV60302931; called by muse, mutect2, varscan2
- MYOM2 | c.1881G>A p.S627= | Silent (SNP) | VAF 20/234 reads (9%) | catalogued as rs376971771; called by muse, mutect2
- PA2G4 | c.408A>G p.T136= | Silent (SNP) | VAF 24/181 reads (13%) | catalogued as COSV57263036; called by muse, mutect2, varscan2
- SCD | c.372C>T p.S124= | Silent (SNP) | VAF 81/219 reads (37%) | catalogued as COSV64853565; called by muse, mutect2, varscan2
- TLN2 | c.7152T>C p.A2384= | Silent (SNP) | VAF 53/286 reads (19%) | catalogued as COSV60895587; called by muse, mutect2, varscan2
- UGT2B11 | c.345C>T p.I115= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV71422930; called by muse, mutect2, varscan2
